Somatic mutation profile of tumor specimen MMRF_1048_1_BM_CD138pos (aliquot MMRF_1048_1_BM_CD138pos_T1_KBS5U_L02851) from MMRF case MMRF_1048, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.5 years (19,544 days).
Specimen MMRF_1048_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc47a3e4-ca3c-4002-b84d-18508251f7fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1048_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1048_1_PB_WBC_C3_KBS5U_L02863; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13e37277-1a7d-4d6f-affa-eabb0c95e035

The open-access MAF lists 84 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Intron 14, 3'UTR 10, 5'UTR 3, 3'Flank 2, Frame Shift Del 2, RNA 1, In Frame Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNKSR2 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 20/29 reads (69%) | catalogued as rs1064794022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750548939, COSV59371010; called by muse, mutect2, varscan2
- CPNE8 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV58852361; called by muse, mutect2
- FMNL3 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 75/85 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs781556112; called by muse, mutect2, varscan2
- IGHJ6 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 25/45 reads (56%) | PolyPhen probably damaging (0.96); catalogued as rs368997749; called by muse, varscan2
- IGHV2-70 | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as rs376400758; called by muse, varscan2
- IGHV2-70 | c.124A>C p.T42P | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs373474286; called by muse, varscan2
- IGLV3-1 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs371563415; called by muse, mutect2, varscan2
- IGLV3-10 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs544313300; called by muse, mutect2, varscan2
- LIMD2 | c.179T>C p.F60S | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs774145429; called by muse, varscan2
- MAGI1 | c.3010G>T p.A1004S (on ENST00000402939 / NM_001033057.2; = p.A1033S on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV100443595; called by muse, mutect2, varscan2
- OR9A4 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 161/312 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1379052061, COSV71886052; called by muse, mutect2, varscan2
- PTPRF | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 119/220 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.257); catalogued as rs751990346; called by muse, mutect2, varscan2
- SEMA4A | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1041986577, COSV61774450; called by muse, mutect2, varscan2
- SSR1 | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as rs774482578; called by muse, mutect2, varscan2
- TAS1R1 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1390328699; called by muse, mutect2
- ZSCAN16 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.08); catalogued as rs1379958897; called by muse, mutect2, varscan2
- ARMH4 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP5MC3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 72/463 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC25C | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- CHM | c.1466T>G p.V489G | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ERMP1 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPR45 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- IGHV2-70D | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, varscan2
- IGHV2-70D | c.136T>G p.F46V | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); called by muse, varscan2
- NSD2 | c.3368A>G p.D1123G | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA4 | c.1103T>G p.V368G | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RBM10 | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- RFTN1 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- RGMB | c.1198C>T p.P400S (on ENST00000513185 / NM_001366508.1; = p.P441S on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.38); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGCD | c.696+7G>T | Splice Region (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- SLC22A11 | c.678del p.R227Gfs*5 | Frame Shift Del (DEL) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- SLC39A7 | c.1118_1119del p.S373Wfs*29 | Frame Shift Del (DEL) | VAF 33/81 reads (41%) | called by mutect2, pindel
- SPATA5 | c.970_975del p.Y324_F325del | In Frame Del (DEL) | VAF 40/99 reads (40%) | called by mutect2, pindel, varscan2
- SYCP1 | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TREX1 | c.166A>G p.T56A (on ENST00000625293 / NM_033629.6; = p.T46A on NM_007248.5) | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM11 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.074); called by muse, varscan2
- ZNF775 | c.1053C>A p.H351Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2
- CCDC171 | c.2389T>C p.L797= | Silent (SNP) | VAF 61/127 reads (48%) | called by muse, mutect2, varscan2
- DSEL | c.1815A>C p.I605= | Silent (SNP) | VAF 77/155 reads (50%) | called by muse, mutect2, varscan2
- FZD8 | c.1038C>T p.G346= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV65968177; called by muse, mutect2, varscan2
- FZD9 | c.549C>T p.P183= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- GPR65 | c.594C>T p.T198= | Silent (SNP) | VAF 22/376 reads (6%) | catalogued as COSV50863028; called by muse, mutect2
- GPRIN3 | c.1179C>T p.H393= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV60884564; called by muse, mutect2, varscan2
- H2AC6 | c.345G>A p.V115= | Silent (SNP) | VAF 130/251 reads (52%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.90G>A p.L30= | Silent (SNP) | VAF 44/44 reads (100%) | called by muse, varscan2
- IGLV3-1 | c.6A>T p.A2= | Silent (SNP) | VAF 67/111 reads (60%) | catalogued as rs1219066661; called by muse, varscan2
- IGLV3-1 | c.24C>T p.L8= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as rs1026216572; called by muse, varscan2
- MAP3K21 | c.997C>T p.L333= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- MUC6 | c.2457G>A p.G819= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV101424852; called by muse, mutect2, varscan2
- PHF1 | c.27C>T p.R9= | Silent (SNP) | VAF 55/117 reads (47%) | called by muse, mutect2, varscan2
- PTK7 | c.1653C>T p.N551= | Silent (SNP) | VAF 52/101 reads (51%) | catalogued as rs143042627, COSV57846504; called by muse, mutect2, varscan2
- SF3B2 | c.747C>T p.P249= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- SRGAP1 | c.126A>G p.R42= | Silent (SNP) | VAF 127/264 reads (48%) | called by muse, mutect2, varscan2
- ABCC9 | c.*895C>T | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- ADAM10 | c.207-4275C>T | Intron (SNP) | VAF 13/33 reads (39%) | catalogued as rs1313194994; called by muse, mutect2, varscan2
- ANKRD42 | c.*727_*729del | 3'UTR (DEL) | VAF 28/62 reads (45%) | called by mutect2, pindel, varscan2
- BDP1 | c.1641-54A>G | Intron (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2
- BNIP2 | c.-203T>G | 5'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- CASP9 | c.*663T>G | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- CCNG2 | c.1-170T>G | Intron (SNP) | VAF 57/99 reads (58%) | called by muse, mutect2, varscan2
- CD300E | c.*1755A>G | 3'UTR (SNP) | VAF 102/220 reads (46%) | called by muse, mutect2, varscan2
- COL11A1 | c.2142+49A>G | Intron (SNP) | VAF 61/144 reads (42%) | catalogued as rs777024800; called by muse, mutect2, varscan2
- COL3A1 | c.-31G>T | 5'UTR (SNP) | VAF 63/142 reads (44%) | called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117681 C>T | 3'Flank (SNP) | VAF 55/104 reads (53%) | catalogued as rs1566984281; called by muse, mutect2, varscan2
- FANCD2 | c.65-458G>T | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- KANSL1L | c.2029+57C>A | Intron (SNP) | VAF 99/206 reads (48%) | called by muse, mutect2, varscan2
- LINC01128 | n.1217T>G | RNA (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- LTB | c.209-65C>T | Intron (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- LTB | c.163-141G>C | Intron (SNP) | VAF 85/200 reads (43%) | catalogued as rs4647180; called by muse, mutect2, varscan2
- MAPK8IP3 | c.745-75C>T | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, varscan2
- MOBP | chr3:39515083 C>T | 3'Flank (SNP) | VAF 45/91 reads (49%) | catalogued as rs997702292; called by muse, mutect2, varscan2
- MYCL | c.*1594T>C | 3'UTR (SNP) | VAF 50/90 reads (56%) | called by muse, mutect2, varscan2
- NAA15 | c.-248T>A | 5'UTR (SNP) | VAF 36/55 reads (65%) | called by muse, mutect2, varscan2
- NAIF1 | c.*1439C>A | 3'UTR (SNP) | VAF 16/36 reads (44%) | catalogued as rs996303043; called by muse, mutect2, varscan2
- PIM2 | c.*708T>C | 3'UTR (SNP) | VAF 42/78 reads (54%) | called by muse, mutect2, varscan2
- PRKAB1 | c.*816C>T | 3'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- RLN3 | c.191-440T>G | Intron (SNP) | VAF 94/145 reads (65%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*2C>T | 3'UTR (SNP) | VAF 17/38 reads (45%) | catalogued as rs752669351, COSV99754835; called by muse, mutect2, varscan2
- SUMO1 | c.*1-111A>G | Intron (SNP) | VAF 156/306 reads (51%) | called by muse, mutect2, varscan2
- TLE1 | c.578-222A>T | Intron (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- TMEM184A | c.645-70C>T | Intron (SNP) | VAF 20/40 reads (50%) | catalogued as rs777340158; called by muse, mutect2
- TYW1B | c.*614C>T | 3'UTR (SNP) | VAF 15/247 reads (6%) | called by muse, mutect2
- VXN | c.342+106C>A | Intron (SNP) | VAF 70/128 reads (55%) | called by muse, mutect2, varscan2
